Somatic mutation profile of tumor specimen C3L-02545-03 (aliquot CPT0113060009) from CPTAC case C3L-02545, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G1; Age at diagnosis: 55.9 years (20,431 days).
Specimen C3L-02545-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a3cd76b-1980-4b2b-bcd0-c6db262a0acf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02545-31 (Blood Derived Normal), aliquot CPT0115230002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b56180a-b5c5-4aed-9b97-dc7e456b3940

The open-access MAF lists 61 somatic variants for this specimen: 46 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 11, Nonsense Mutation 3, Frame Shift Del 2, RNA 2, Intron 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 165/357 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 42/44 reads (95%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2
- SOS1 | c.697A>T p.N233Y | Missense Mutation (SNP) | VAF 30/51 reads (59%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen possibly damaging (0.671); catalogued as rs1057519963, COSV67673722; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADPRH | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 276/612 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761010216, COSV63695476; called by muse, mutect2, varscan2
- ADSS1 | c.1126G>A p.G376S | Missense Mutation (SNP) | VAF 69/193 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs756353033; called by muse, mutect2, varscan2
- ADSS1 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 93/226 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.551); catalogued as rs542898507; called by muse, mutect2, varscan2
- ARID1A | c.3379C>T p.Q1127* | Nonsense Mutation (SNP) | VAF 124/223 reads (56%) | catalogued as COSV61385668; called by muse, mutect2, varscan2
- B3GAT1 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as rs776452256, COSV56998970; called by muse, mutect2, varscan2
- CAMK2A | c.1393G>A p.V465I (on ENST00000348628 / NM_171825.2; = p.V476I on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 181/378 reads (48%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.012); catalogued as rs764264581, COSV62245867; called by muse, mutect2, varscan2
- CEL | c.341G>A p.R114K (on ENST00000673714; = p.R111K on NM_001807.6) | Missense Mutation (SNP) | VAF 137/290 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs1429601010; called by muse, mutect2, varscan2
- CELF6 | c.544G>T p.G182W | Missense Mutation (SNP) | VAF 92/230 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54717433; called by muse, mutect2, varscan2
- CFAP92 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 72/155 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.401); catalogued as rs757852747, COSV54049079, COSV99414701; called by muse, mutect2, varscan2
- CHRNA7 | c.80G>T p.R27M | Missense Mutation (SNP) | VAF 74/151 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100181149; called by muse, mutect2, varscan2
- CORO1A | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 101/259 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1199044265; called by muse, mutect2, varscan2
- CRYBG1 | c.5830C>T p.R1944C | Missense Mutation (SNP) | VAF 32/37 reads (86%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs189629498, COSV64812401; called by muse, mutect2, varscan2
- HIVEP3 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 90/190 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs142189176, COSV56014171; called by muse, mutect2, varscan2
- ICE1 | c.6065T>A p.F2022Y | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as COSV104409458; called by muse, mutect2
- IL1RAPL1 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 73/169 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs778199033, COSV56261367; called by muse, mutect2, varscan2
- KIF2B | c.1688G>A p.R563K | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99276496; called by muse, mutect2, varscan2
- LEPROT | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as COSV60765103; called by muse, mutect2
- MAP2K7 | c.870C>G p.D290E | Missense Mutation (SNP) | VAF 81/179 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as COSV67608111; called by muse, mutect2, varscan2
- MAP3K11 | c.1940G>A p.R647H | Missense Mutation (SNP) | VAF 149/338 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.232); catalogued as rs747732702; called by muse, mutect2, varscan2
- MMADHC | c.34G>C p.V12L | Missense Mutation (SNP) | VAF 128/287 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.115); catalogued as COSV57574726; called by muse, mutect2, varscan2
- NCKAP5 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs777479794, COSV58447015, COSV58474004; called by muse, mutect2, varscan2
- NOP14 | c.2038G>T p.A680S | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0.138); catalogued as COSV58626377; called by muse, mutect2, varscan2
- NR1D2 | c.566T>C p.I189T | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs756958889; called by muse, varscan2
- RTP5 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as rs755794520; called by muse, mutect2, varscan2
- STH | c.156G>A p.W52* | Nonsense Mutation (SNP) | VAF 23/342 reads (7%) | catalogued as rs867338908; called by muse, mutect2
- VPS8 | c.2206C>T p.R736C (on ENST00000625842 / NM_001349294.1; = p.R734C on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/210 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs781736257, COSV54998419; called by muse, mutect2, varscan2
- ARID1A | c.4899del p.M1634* | Frame Shift Del (DEL) | VAF 38/105 reads (36%) | called by mutect2, pindel, varscan2
- C1QTNF7 | c.681C>A p.N227K | Missense Mutation (SNP) | VAF 80/178 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CYP2C9 | c.634T>A p.W212R | Missense Mutation (SNP) | VAF 108/235 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- FAM178B | c.734+1G>A p.X245_splice | Splice Site (SNP) | VAF 49/111 reads (44%) | called by muse, mutect2, varscan2
- GPRASP2 | c.626A>C p.Y209S | Missense Mutation (SNP) | VAF 91/188 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ISCA2 | c.28A>G p.T10A | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- LOXHD1 | c.6703G>T p.E2235* (on ENST00000642948; = p.E2173* on NM_144612.7) | Nonsense Mutation (SNP) | VAF 246/562 reads (44%) | called by muse, mutect2, varscan2
- OCSTAMP | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- OR56A1 | c.637G>T p.D213Y | Missense Mutation (SNP) | VAF 80/175 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RABEP1 | c.14del p.G5Afs*14 | Frame Shift Del (DEL) | VAF 27/82 reads (33%) | called by mutect2, pindel, varscan2
- SNRNP200 | c.2761G>A p.G921S | Missense Mutation (SNP) | VAF 160/322 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SNTG1 | c.1039-4C>G | Splice Region (SNP) | VAF 113/318 reads (36%) | called by mutect2, varscan2
- TIMM23 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 99/251 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- TNFRSF1A | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 56/210 reads (27%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- ZNF470 | c.1447T>C p.C483R | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF721 | c.2002T>A p.W668R (on ENST00000338977; = p.W680R on NM_133474.4) | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF79 | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 94/191 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DCTN1 | c.3267C>T p.D1089= | Silent (SNP) | VAF 152/399 reads (38%) | called by muse, mutect2, varscan2
- DTX1 | c.1653C>T p.L551= | Silent (SNP) | VAF 48/146 reads (33%) | called by muse, mutect2, varscan2
- KCNE5 | c.168C>T p.G56= | Silent (SNP) | VAF 209/500 reads (42%) | catalogued as COSV100927719; called by muse, mutect2, varscan2
- KLK5 | c.774C>T p.L258= | Silent (SNP) | VAF 75/182 reads (41%) | catalogued as rs766848629; called by muse, mutect2, varscan2
- PER2 | c.2619C>T p.H873= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as rs376874446; called by muse, mutect2, varscan2
- PIP5KL1 | c.1017G>A p.E339= (on ENST00000388747 / NM_001135219.2; = p.E136= on NM_173492.1) | Silent (SNP) | VAF 12/221 reads (5%) | catalogued as rs1439089717; called by muse, mutect2
- POU2F2 | c.420G>T p.P140= | Silent (SNP) | VAF 127/332 reads (38%) | called by muse, mutect2
- SH2D3C | c.891G>A p.V297= (on ENST00000314830 / NM_170600.3; = p.V140= on NM_005489.4) | Silent (SNP) | VAF 223/492 reads (45%) | catalogued as rs780714916; called by muse, mutect2, varscan2
- TMPO | c.213C>G p.R71= | Silent (SNP) | VAF 140/222 reads (63%) | catalogued as rs910746839; ClinVar: likely benign; called by muse, mutect2, varscan2
- XKR9 | c.114T>C p.Y38= | Silent (SNP) | VAF 63/109 reads (58%) | called by muse, mutect2, varscan2
- ZNF276 | c.762C>T p.D254= (on ENST00000443381 / NM_001113525.2; = p.D179= on NM_152287.4) | Silent (SNP) | VAF 283/594 reads (48%) | called by muse, mutect2, varscan2
- DPY19L2 | c.1580+3011G>A | Intron (SNP) | VAF 19/110 reads (17%) | called by muse, mutect2, varscan2
- SLC22A20P | n.924A>G | RNA (SNP) | VAF 85/186 reads (46%) | catalogued as rs763103604; called by muse, mutect2, varscan2
- SPATA31C1 | n.1102C>T | RNA (SNP) | VAF 224/502 reads (45%) | catalogued as rs562949328; called by muse, mutect2, varscan2
- TYMP | c.516+10G>A | Intron (SNP) | VAF 163/374 reads (44%) | catalogued as rs552829713, COSV52688378; ClinVar: uncertain significance; called by muse, mutect2, varscan2
